Surgical pathology report (de-identified scan), TCGA case TCGA-06-2558, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-2558-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

TCGA-06-2558

CLINICAL HISTORY

[REDACTED] with headaches, has enhancing necrotic mass associated with vasogenic edema and mass effect in the right frontal lobe.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, biopsy

B: Brain, tumor resection

HISTOLOGICAL DIAGNOSIS:

A and B. Brain, right frontal, excisional biopsies:

1. Glioblastoma.

2. MIB-1 proliferation index: 25%.

See Microscopy Description and Comment.

COMMENT

The specimens are portions of cerebrum that are infiltrated and focally effaced by an astrocytic neoplastic proliferation that has nuclear anaplasia, mitotic activity and high proliferation index, prominent microvascular cellular proliferation with necrosis, extensive karyorrhexis, and zones of necrosis, a glioblastoma..

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on tissue block

[page 2 of 3]
TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain, biopsy, touch prep and smears: High histological grade glioma (C/W glioblastoma). [REDACTED] Touch preparation smears performed at [REDACTED] Hospital and results reported to the Physician of Record.

[REDACTED]

GROSS DESCRIPTION

A.

Brain, biopsy:
"Right frontal brain tumor," received fresh, several fragments, 2.8 cm. In aggregate. Semi firm, glistening, tannish-brown, focally hemorrhagic. In total, A1-A3.

B.

Brain, biopsy: FIXATIVE: Fresh. NO. PIECES: multiple tan gray soft tissue fragments. SIZE/VOL: 7.5 cm aggregate. CASSETTES: 1-3, NS.

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates gliofibrillogenesis by the neoplastic cells in the solid tumor areas. In the infiltrating surrounding zones there is prominent reactive astrocytosis. More than 90% of neoplastic cells strongly over express the p53 protein. With the MIB-1 there is a proliferation index of about 25% in the solid areas of tumor.

The immunophenotype is that of a high histological grade glioma.

ICD-9(s):

239.6 239.6

[REDACTED]

[page 3 of 3]
Histo Data

Part A: Brain biopsy

Taken:	Received:		
Stain/cnt	Block Ordered Comment		
H/E x 1	1		
H/E x 1	2		
mGFAP-DA x 1	3		
H/E x 1	3		
MIB1-DA x 1	3		
P53DO7 x 1	3		

Part B: Brain, tumor resection

Taken:	Received:		
Stain/cnt	Block Ordered Comment		
H/E x 1	1		
H/E x 1	2		
CD163 Vector x 1	3		
mGFAP-DA x 1	3		
H/E x 1	3		
MGMT x 1	3		
MIB1-DA x 1	3		

*** End of Report ***

Source: NCI Genomic Data Commons file a13e5fcb-fe7c-4f9d-a482-063d6c4b006f (TCGA-06-2558.15262BAA-42BA-49A8-A63D-071E1B34AB89.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).